Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7839, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7839-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

1. Kidney, right, partial nephrectomy:
- Renal cell carcinoma with papillary features, suggestive of papillary Type I.
- Capsule is free of tumor.
- Chronic interstitial nephritis, occasional incipient lesion present.
2. Adipose tissue, over tumor, excision: Cluster of tumor cells and fat, see Note.
3. Gallbladder, cholecystectomy: Chronic cholecystitis.

NOTE: The group of tumor cells present in the fat appears to be floaters or contamination. Staining for CK7 is strongly positive.

RENAL PELVIS: Resection/Nephroureterectomy, Partial

Procedure

Nephrectomy, partial

Specimen Laterality

Right

Tumor Size

Greatest dimension: 4.3 cm

Additional dimensions: 2.2 cm

Histologic Type

Suggestive of papillary carcinoma, type I

Patient Identification

[page 2 of 3]
Associated Epithelial Lesions

Occasional

Tumor Configuration

Papillary

Margins

Adipose tissue, perirenal

Margin(s) involved by invasive carcinoma

Lymph-Vascular Invasion

Not identified

CLINICAL INFORMATION: Allocate Order to [REDACTED] Brief Clinical History: [REDACTED] Y
[REDACTED] with incidentally found R renal mass, hemangioma on liver [REDACTED]
cholecystitis Specimen Taken For Protocol: [REDACTED]

PROCEDURE: Pre-Operative Diagnosis: Right renal mass Post-Operative Diagnosis:
same Operative Findings: as dictated

SPECIMENS SUBMITTED: 1. KIDNEY WEDGE EXCISION, RIGHT, Renal
2. FAT, Over tumor
3. GALLBLADDER

GROSS DESCRIPTION: Received fresh with patient's name, medical record number, and further specified as:

1. "Renal mass deep margin ink" is a red-tan soft tissue mass with one surface inked in black measuring 5.2 x 3.4 x 3 cm. The remainder of specimen is inked in green in the frozen section room. The specimen is cut to reveal a tan solid tumor measuring 4.3 x 2.2 cm with a central area of hemorrhage and necrosis. There is a rim of normal renal parenchyma on one side measuring up to 0.6 cm. Approximately 0.6 x 0.6 x 0.3 cm of tumor tissue, and 0.1 x 0.1 x 0.1 cm of normal kidney parenchyma is procured for the [REDACTED] Lab on [REDACTED] by [REDACTED]. In the [REDACTED], the specimen matches the above description. The tumor can be grossly noted and it appears to be at the previously inked blue margin. Representative sections are submitted in white cassettes labeled [REDACTED] 1A-1H as follows: 1A-1C – tumor and closest resection margin inked in blue; 1D-1G – tumor and papillary aspect; 1H – normal renal parenchyma.

Patient Identification

[page 3 of 3]
-
-
2. "Fat over tumor, outer margin". It consists of multiple yellow fibroadipose tissue measuring in aggregate 4.2 x 3.5 x 0.6 cm. A smaller tan piece measuring 1.3 x 0.5 x 0.4 cm presenting small papillae can be grossly noted. The specimen is serially sectioned revealing a small area of hemorrhage and a similar papillary tan structure. The specimen is entirely submitted in white cassette labeled [REDACTED] 2A-2F.
3. "Gallbladder". It consists of a 9.8 x 3.6 x 2.8-cm gallbladder specimen. The serosal surface is unremarkable. The specimen is open to reveal a red-tan mucosa surface and approximately 10 ml of green/brown bile. No gallstones are identified. Approximately 1 x 1 x 0.2 cm of tissue is procured for [REDACTED] Lab and 1 x 1 x 0.2 cm for the [REDACTED]. The procurement was performed by [REDACTED] on 03/01/10 at 2:15 p.m. In the [REDACTED] the specimen matches the above description. The mucosa appears green and velvety with a maximum thickness of 0.5 cm. The bile duct is probed. It measures 0.3 cm in maximal diameter. Representative sections are submitted in 2 white cassettes labeled [REDACTED] 3A and 3B (3A – bile duct and vascular margin; 3B – representative section of gallbladder).

Gross description dictated by [REDACTED]

No consultants

Patient Identification

Source: NCI Genomic Data Commons file 3b399b5c-1ac8-46a9-860c-569f8bfae97a (TCGA-DW-7839.DC296EC4-9FBC-4EFF-98DB-980AE764E36D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).